Somatic mutation profile of tumor specimen C3L-06940-01 (aliquot CPT0393620006) from CPTAC case C3L-06940, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.3 years (25,321 days).
Specimen C3L-06940-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c0413a-fc14-4d7b-b296-0db835f47ece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06940-32 (Blood Derived Normal), aliquot CPT0390860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a335e83a-ae29-433b-9a85-d612b38240cf

The open-access MAF lists 236 somatic variants for this specimen: 160 protein-altering or splice-affecting, 66 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 66, Nonsense Mutation 9, Intron 5, Frame Shift Ins 3, Splice Site 3, Frame Shift Del 2, RNA 2, In Frame Del 2, Splice Region 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 262/463 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 166/470 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2
- RUNX1 | c.239G>A p.R80H (on ENST00000344691 / NM_001001890.3; = p.R107H on NM_001754.5) | Missense Mutation (SNP) | VAF 178/361 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1569084106, CM164535, COSV100276589, COSV55867689, COSV55868826; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 108/293 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV52206136; called by muse, mutect2, varscan2
- ACAN | c.6580G>A p.D2194N | Missense Mutation (SNP) | VAF 116/496 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1238866748, COSV61361891; called by muse, mutect2, varscan2
- ACAT2 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV65454556; called by muse, mutect2, varscan2
- ADAMTS10 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1188791985, COSV99546735; called by muse, mutect2, varscan2
- ADAMTS2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 123/594 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51072681; called by muse, mutect2, varscan2
- AMD1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 81/303 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64387323; called by muse, mutect2, varscan2
- ANKRD30BL | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs9752400; called by muse, mutect2, varscan2
- ANTKMT | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1475087409; called by muse, mutect2, varscan2
- ARAP1 | c.1271G>A p.R424Q (on ENST00000393609 / NM_001040118.2; = p.R179Q on NM_015242.4) | Missense Mutation (SNP) | VAF 142/494 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs143371904; called by muse, mutect2, varscan2
- BPIFB1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV53608278; called by muse, mutect2, varscan2
- BTBD8 | c.344dup p.L115Ffs*15 | Frame Shift Ins (INS) | VAF 26/133 reads (20%) | catalogued as rs761559434; called by mutect2, pindel, varscan2
- CASP10 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV53780051; called by muse, mutect2, varscan2
- CDH10 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52582075, COSV52588300; called by mutect2, varscan2
- CDH22 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100952933; called by muse, mutect2
- CHD4 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs765576027; called by muse, mutect2, varscan2
- CILP | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 166/503 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs763830525, COSV56023045; called by muse, mutect2, varscan2
- CILP2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 152/539 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs759288774, COSV52272288; called by muse, mutect2, varscan2
- COX6A2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 157/534 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760787848, COSV99791418, COSV99791464; called by muse, mutect2, varscan2
- CRLF1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 106/426 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs778815231; called by muse, mutect2, varscan2
- DAPK1 | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs755550317, COSV63783974; called by muse, mutect2, varscan2
- DGKI | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1286187627, COSV55941126; called by muse, mutect2, varscan2
- EFNA5 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs754669041; called by muse, mutect2, varscan2
- ELAPOR2 | c.2816C>T p.A939V (on ENST00000450689 / NM_001142749.3; = p.A772V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/373 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51887223; called by muse, mutect2, varscan2
- EPOP | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 164/628 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs774071518; called by muse, mutect2, varscan2
- EYA2 | c.889-1G>A p.X297_splice | Splice Site (SNP) | VAF 142/330 reads (43%) | catalogued as rs1296730373; called by muse, mutect2, varscan2
- FAM187B | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 199/618 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs527754765, COSV100219913, COSV61201560; called by muse, mutect2, varscan2
- FLNC | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 138/674 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs758342140, COSV57954318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 140/546 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60415811, COSV60441208; called by muse, mutect2, varscan2
- FOXF1 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 101/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446005869; called by muse, mutect2, varscan2
- FREM2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 145/539 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV54827957; called by muse, mutect2, varscan2
- FREM3 | c.5728C>T p.R1910* | Nonsense Mutation (SNP) | VAF 56/271 reads (21%) | catalogued as rs886043245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALK1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs752592319; called by muse, mutect2, varscan2
- GRIA2 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV52386949; called by muse, mutect2, varscan2
- ITGB4 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 199/429 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs756104984; called by muse, mutect2, varscan2
- ITGB6 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs763356279; called by muse, mutect2, varscan2
- ITIH1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1454833049, COSV56254612; called by muse, mutect2, varscan2
- KCNIP1 | c.269C>T p.A90V (on ENST00000411494 / NM_001034837.3; = p.A79V on NM_014592.4) | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1287679607; called by muse, mutect2, varscan2
- KIF1C | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 159/386 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs200230098, COSV100297314; called by muse, mutect2, varscan2
- LRRTM1 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 127/424 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs745448568, COSV99703132; called by muse, mutect2, varscan2
- MAML2 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs772799140, COSV73263818; called by muse, mutect2, varscan2
- MMP11 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs776950374, COSV53155854; called by muse, varscan2
- MYO16 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs573011173, COSV104377749; called by muse, mutect2, varscan2
- NCOR2 | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs781631837, COSV100657399, COSV62297949; called by muse, mutect2, varscan2
- OR2T1 | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 189/595 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100822310, COSV63542604; called by muse, mutect2, varscan2
- PCDHGA4 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.493); catalogued as rs766818568, COSV53916393, COSV99537844; called by muse, mutect2, varscan2
- PIK3CA | c.3017T>G p.L1006R | Missense Mutation (SNP) | VAF 140/457 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55886376, COSV55983945; called by muse, mutect2
- PIK3R1 | c.1378A>C p.S460R (on ENST00000521381 / NM_181523.3; = p.S190R on NM_181504.4) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV57125132; called by muse, mutect2, varscan2
- PLXNA3 | c.3965C>T p.T1322M | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1557208154; called by muse, mutect2, varscan2
- PREX1 | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs753042714, COSV64256039; called by muse, mutect2, varscan2
- PRRG2 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 30/600 reads (5%) | catalogued as rs761664639; called by muse, mutect2
- PTPRG | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 124/397 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs777373171; called by muse, mutect2, varscan2
- RAPGEF6 | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | catalogued as COSV57246520; called by muse, mutect2, varscan2
- ROBO4 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs200463910; called by muse, mutect2, varscan2
- SDHAF2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 118/386 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs778585796, COSV57100073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPTIN1 | c.190C>T p.R64C (on ENST00000321367; = p.R17C on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs755491420, COSV100363136, COSV58442273; called by muse, mutect2
- SF3B4 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 136/451 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs917974801; called by muse, mutect2, varscan2
- SH3GL3 | c.61dup p.I21Nfs*5 | Frame Shift Ins (INS) | VAF 56/201 reads (28%) | catalogued as rs745757313; called by mutect2, pindel, varscan2
- SHISA7 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as rs941242224, COSV66244455; called by muse, varscan2
- TAB2 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 57/214 reads (27%) | catalogued as COSV53851577; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as rs149504543; called by muse, mutect2, varscan2
- TRIM43 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 101/515 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99720210; called by muse, mutect2, varscan2
- TTN | c.77686G>T p.G25896C (on ENST00000591111; = p.G18472C on NM_003319.4) | Missense Mutation (SNP) | VAF 109/403 reads (27%) | PolyPhen possibly damaging (0.553); catalogued as rs786205375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.56882C>T p.T18961I (on ENST00000591111; = p.T11537I on NM_003319.4) | Missense Mutation (SNP) | VAF 113/370 reads (31%) | PolyPhen probably damaging (0.998); catalogued as rs1342930607; called by muse, mutect2, varscan2
- U2AF2 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148965195; called by muse, mutect2, varscan2
- UNC5B | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 121/495 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.595); catalogued as rs780781213, COSV58978916; called by muse, mutect2, varscan2
- VPS50 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52494484; called by muse, mutect2, varscan2
- VWCE | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs548971972, COSV100075657; called by muse, mutect2, varscan2
- ZNF512B | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 103/515 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV99412972; called by muse, mutect2, varscan2
- ADAMTS19 | c.2695C>A p.L899I | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- AMPH | c.692T>A p.M231K | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ARHGAP28 | c.950del p.L317* (on ENST00000383472 / NM_001366230.1; = p.L158* on NM_001010000.3) | Frame Shift Del (DEL) | VAF 35/96 reads (36%) | called by mutect2, pindel, varscan2
- ATPAF1 | c.825A>C p.Q275H (on ENST00000574428; = p.Q298H on NM_022745.4) | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BNC1 | c.1091_1093del p.K364del | In Frame Del (DEL) | VAF 94/410 reads (23%) | called by pindel, varscan2
- C6orf132 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 187/593 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1E | c.1238C>A p.A413E | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1F | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 123/206 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CBS | c.226A>C p.I76L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CCDC172 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- CD58 | c.536A>C p.N179T | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CDH9 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, varscan2
- CDK5R1 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 32/739 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELSR2 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 142/431 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CEMIP | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 12/413 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- CNTN6 | c.1652T>A p.F551Y | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COBLL1 | c.3571_3577del p.R1191Afs*81 (on ENST00000392717; = p.R1153Afs*81 on NM_014900.5) | Frame Shift Del (DEL) | VAF 55/299 reads (18%) | called by mutect2, pindel, varscan2
- COL15A1 | c.2446T>C p.S816P | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- COL6A5 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 96/332 reads (29%) | called by muse, mutect2, varscan2
- CPA2 | c.458T>C p.F153S | Missense Mutation (SNP) | VAF 80/355 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CRHBP | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CTTNBP2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 97/439 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX21 | c.153_158del p.F52_P53del | In Frame Del (DEL) | VAF 53/255 reads (21%) | called by mutect2, pindel, varscan2
- DNAH10 | c.546A>C p.E182D (on ENST00000409039; = p.E121D on NM_207437.3) | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- DOT1L | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DPY19L3 | c.1399T>G p.L467V | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- DYNC2H1 | c.8442C>A p.S2814R | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ENGASE | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 160/702 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ENTPD7 | c.1432T>C p.F478L | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- EVX2 | c.1173T>G p.S391R | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EYS | c.4502T>A p.I1501K | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FOXN4 | c.471C>T p.C157= | Splice Region (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- GALR2 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 132/686 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJC1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 162/534 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GKN1 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI3 | c.1886A>C p.K629T | Missense Mutation (SNP) | VAF 125/519 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTCD | c.1873A>C p.N625H (on ENST00000360505 / NM_001031720.3; = p.N538H on NM_024751.3) | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HOXA10 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 28/738 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXA6 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 111/553 reads (20%) | called by muse, mutect2, varscan2
- HUNK | c.1558T>G p.F520V | Missense Mutation (SNP) | VAF 126/365 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- IGKV3D-7 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- IL17RD | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 158/481 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IQCN | c.1817T>A p.I606N | Missense Mutation (SNP) | VAF 161/475 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IRX4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 171/478 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNU1 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCTD3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KLK2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 131/425 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT6B | c.1077+1G>A p.X359_splice | Splice Site (SNP) | VAF 99/277 reads (36%) | called by muse, mutect2, varscan2
- LTBP4 | c.1631C>T p.P544L (on ENST00000308370 / NM_001042544.1; = p.P507L on NM_003573.2) | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NAALAD2 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 121/386 reads (31%) | called by muse, mutect2, varscan2
- NCOR1 | c.2195A>C p.K732T | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NOP14 | c.1270T>G p.Y424D | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NPAS3 | c.943G>A p.A315T (on ENST00000356141 / NM_001164749.2; = p.A283T on NM_022123.3) | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR11H2 | c.91C>A p.L31I (on ENST00000556246; = p.L42I on NM_001197287.1) | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, varscan2
- OR5B17 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OSTN | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PADI6 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 107/392 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.2879C>T p.P960L | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNISR | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKCG | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PRMT3 | c.483dup p.L162Ifs*12 | Frame Shift Ins (INS) | VAF 97/417 reads (23%) | called by mutect2, pindel, varscan2
- PYHIN1 | c.1368A>C p.E456D | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RBFOX2 | c.137A>T p.K46M | Missense Mutation (SNP) | VAF 104/490 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RIMS1 | c.3739A>G p.M1247V | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF34 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 117/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- RPGRIP1L | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RTN4RL1 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RTN4RL1 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 40/342 reads (12%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1475A>G p.E492G (on ENST00000265814 / NM_001198628.1; = p.E465G on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/422 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SEM1 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 126/421 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SLC17A5 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A6 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SMARCA4 | c.4688A>C p.K1563T | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- SNAPIN | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SYNE2 | c.17695G>A p.E5899K | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TANC2 | c.3790G>T p.A1264S | Missense Mutation (SNP) | VAF 182/418 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TAPBP | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 198/451 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TCAIM | c.1423T>C p.Y475H | Missense Mutation (SNP) | VAF 112/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCF7L2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TDRD15 | c.1818T>G p.D606E | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.412); called by muse, mutect2
- TTC21B | c.2890A>T p.R964* | Nonsense Mutation (SNP) | VAF 65/243 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.14731G>T p.A4911S | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.067); called by mutect2, varscan2
- VCAN | c.4059A>C p.E1353D | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WSCD2 | c.1610A>C p.K537T | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZDBF2 | c.4925G>T p.G1642V | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZDHHC13 | c.810A>C p.K270N | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF775 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA3 | c.2182C>T p.L728= | Silent (SNP) | VAF 134/432 reads (31%) | called by muse, mutect2, varscan2
- ABCA3 | c.1812C>A p.I604= | Silent (SNP) | VAF 130/396 reads (33%) | called by muse, mutect2, varscan2
- ABI3BP | c.714G>A p.R238= | Silent (SNP) | VAF 93/291 reads (32%) | catalogued as COSV99427912; called by muse, mutect2, varscan2
- ARFGEF3 | c.4161G>A p.L1387= | Silent (SNP) | VAF 91/372 reads (24%) | catalogued as rs1177180570; called by muse, mutect2, varscan2
- ARHGAP22 | c.1152C>T p.G384= | Silent (SNP) | VAF 228/752 reads (30%) | catalogued as rs1474604770, COSV50973244; called by muse, mutect2, varscan2
- ASTN2 | c.684C>T p.Y228= | Silent (SNP) | VAF 160/482 reads (33%) | catalogued as rs753397797, COSV57754418; called by muse, mutect2, varscan2
- ATG9B | c.1023G>A p.R341= | Silent (SNP) | VAF 284/601 reads (47%) | called by muse, mutect2, varscan2
- BTNL9 | c.774G>A p.A258= | Silent (SNP) | VAF 66/325 reads (20%) | called by muse, mutect2, varscan2
- CACNA1G | c.1191G>A p.Q397= | Silent (SNP) | VAF 126/527 reads (24%) | called by muse, mutect2, varscan2
- CCDC114 | c.1794C>T p.H598= | Silent (SNP) | VAF 140/523 reads (27%) | catalogued as rs758832949, COSV59557050; called by muse, mutect2, varscan2
- CCDC153 | c.459G>A p.A153= | Silent (SNP) | VAF 109/349 reads (31%) | catalogued as rs143016004; called by muse, mutect2, varscan2
- CCDC9 | c.522C>T p.I174= | Silent (SNP) | VAF 84/350 reads (24%) | catalogued as rs539946123; called by muse, mutect2, varscan2
- COL12A1 | c.6975G>A p.V2325= | Silent (SNP) | VAF 95/344 reads (28%) | called by muse, mutect2, varscan2
- COL22A1 | c.1731C>T p.P577= | Silent (SNP) | VAF 96/377 reads (25%) | catalogued as rs559519347; called by muse, varscan2
- DGCR8 | c.1083C>T p.N361= | Silent (SNP) | VAF 125/408 reads (31%) | catalogued as rs180676903; called by muse, mutect2, varscan2
- DISP3 | c.1722C>T p.A574= | Silent (SNP) | VAF 119/295 reads (40%) | catalogued as rs372251607, COSV99609195; called by muse, mutect2, varscan2
- DNAH9 | c.7143T>G p.A2381= | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- DNAJC6 | c.345T>G p.S115= | Silent (SNP) | VAF 98/259 reads (38%) | called by muse, mutect2, varscan2
- EBF3 | c.1299C>A p.G433= (on ENST00000355311 / NM_001375392.1; = p.G424= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 115/437 reads (26%) | catalogued as COSV62478935; called by muse, mutect2, varscan2
- ECM1 | c.1005G>T p.L335= | Silent (SNP) | VAF 124/427 reads (29%) | catalogued as COSV60874351; called by muse, mutect2, varscan2
- ENO1 | c.948G>A p.V316= | Silent (SNP) | VAF 147/353 reads (42%) | catalogued as rs1188844085, COSV52303146; called by muse, mutect2, varscan2
- FOXI3 | c.600C>T p.N200= | Silent (SNP) | VAF 138/476 reads (29%) | catalogued as COSV67917045; called by muse, mutect2, varscan2
- GASK1A | c.972G>A p.G324= | Silent (SNP) | VAF 167/533 reads (31%) | called by muse, mutect2, varscan2
- HAPLN3 | c.642G>A p.A214= | Silent (SNP) | VAF 197/596 reads (33%) | catalogued as rs151250721; called by muse, mutect2, varscan2
- HEYL | c.66A>G p.Q22= | Silent (SNP) | VAF 68/310 reads (22%) | called by muse, mutect2, varscan2
- IRAG2 | c.2595A>G p.Q865= | Silent (SNP) | VAF 14/450 reads (3%) | called by muse, mutect2
- ITPRID1 | c.748C>A p.R250= | Silent (SNP) | VAF 98/500 reads (20%) | catalogued as rs748849900, COSV60076719; called by muse, mutect2, varscan2
- JPH2 | c.846T>C p.D282= | Silent (SNP) | VAF 203/850 reads (24%) | catalogued as rs976324787; called by muse, mutect2, varscan2
- KDM6B | c.4659C>T p.S1553= | Silent (SNP) | VAF 85/209 reads (41%) | called by muse, mutect2, varscan2
- LILRB5 | c.897C>T p.H299= | Silent (SNP) | VAF 24/668 reads (4%) | called by muse, mutect2
- LOXL4 | c.619C>T p.L207= | Silent (SNP) | VAF 135/451 reads (30%) | called by muse, mutect2, varscan2
- LSS | c.1662G>A p.A554= | Silent (SNP) | VAF 50/280 reads (18%) | catalogued as rs762730550, COSV100710893; called by muse, mutect2, varscan2
- MAGEC1 | c.2580C>A p.S860= | Silent (SNP) | VAF 114/191 reads (60%) | called by muse, mutect2, varscan2
- MED24 | c.2004G>T p.S668= | Silent (SNP) | VAF 171/407 reads (42%) | catalogued as COSV62417855; called by muse, mutect2, varscan2
- MRC1 | c.2149T>C p.L717= | Silent (SNP) | VAF 103/375 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.17043G>A p.E5681= | Silent (SNP) | VAF 148/500 reads (30%) | called by muse, mutect2, varscan2
- MYEF2 | c.309C>T p.F103= | Silent (SNP) | VAF 67/265 reads (25%) | called by muse, mutect2, varscan2
- NATD1 | c.27G>A p.P9= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as rs1260918408; called by muse, mutect2, varscan2
- NIPAL1 | c.1029A>C p.G343= | Silent (SNP) | VAF 101/330 reads (31%) | called by muse, mutect2, varscan2
- NOTCH4 | c.5868G>A p.L1956= | Silent (SNP) | VAF 165/479 reads (34%) | catalogued as COSV66683946; called by muse, mutect2, varscan2
- NRXN1 | c.480G>A p.P160= | Silent (SNP) | VAF 144/516 reads (28%) | catalogued as rs771181102, COSV68003367; called by muse, mutect2, varscan2
- OR52H1 | c.27C>T p.Y9= (on ENST00000322653; = p.Y15= on NM_001005289.1) | Silent (SNP) | VAF 96/348 reads (28%) | catalogued as rs774095903; called by muse, mutect2, varscan2
- OR6B1 | c.132C>A p.I44= | Silent (SNP) | VAF 82/492 reads (17%) | called by muse, mutect2, varscan2
- OR6N2 | c.720C>T p.T240= | Silent (SNP) | VAF 96/311 reads (31%) | catalogued as COSV100210563; called by muse, mutect2, varscan2
- PHB | c.327C>T p.S109= | Silent (SNP) | VAF 228/554 reads (41%) | called by muse, mutect2, varscan2
- PIK3CG | c.2466C>T p.A822= | Silent (SNP) | VAF 69/392 reads (18%) | catalogued as rs1442562966; called by muse, mutect2, varscan2
- PLCG1 | c.189C>T p.S63= | Silent (SNP) | VAF 196/467 reads (42%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1980T>C p.T660= | Silent (SNP) | VAF 68/320 reads (21%) | catalogued as COSV64564235; called by muse, mutect2, varscan2
- PNMA3 | c.1344C>T p.N448= | Silent (SNP) | VAF 149/244 reads (61%) | catalogued as rs782310746, COSV99058941; called by muse, mutect2, varscan2
- PPEF1 | c.735C>T p.F245= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- RBM15B | c.537G>A p.L179= | Silent (SNP) | VAF 139/431 reads (32%) | called by muse, mutect2, varscan2
- RRM2B | c.873C>T p.D291= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- SHROOM3 | c.3648C>T p.A1216= | Silent (SNP) | VAF 109/386 reads (28%) | catalogued as rs778932431, COSV56024087; called by muse, mutect2, varscan2
- SLC49A3 | c.165C>T p.D55= | Silent (SNP) | VAF 75/249 reads (30%) | catalogued as rs201753792; called by muse, mutect2, varscan2
- SLC5A1 | c.316C>T p.L106= | Silent (SNP) | VAF 118/368 reads (32%) | called by muse, mutect2, varscan2
- SMC1A | c.2997C>T p.I999= | Silent (SNP) | VAF 107/172 reads (62%) | called by muse, mutect2, varscan2
- SORCS3 | c.3039C>T p.Y1013= | Silent (SNP) | VAF 79/300 reads (26%) | called by muse, mutect2, varscan2
- STXBP4 | c.342G>A p.Q114= | Silent (SNP) | VAF 68/331 reads (21%) | called by muse, mutect2, varscan2
- TAF6 | c.369C>T p.P123= | Silent (SNP) | VAF 87/358 reads (24%) | called by muse, mutect2, varscan2
- TINAG | c.756T>C p.A252= | Silent (SNP) | VAF 60/186 reads (32%) | called by mutect2, varscan2
- TKTL2 | c.75C>T p.I25= | Silent (SNP) | VAF 61/344 reads (18%) | catalogued as COSV54921390; called by muse, mutect2, varscan2
- TRMT9B | c.738G>A p.S246= | Silent (SNP) | VAF 106/354 reads (30%) | catalogued as rs372929039; called by muse, mutect2, varscan2
- TUBB8 | c.585C>T p.N195= | Silent (SNP) | VAF 97/424 reads (23%) | catalogued as rs550484517, COSV59114509; called by muse, varscan2
- UPRT | c.318C>T p.I106= | Silent (SNP) | VAF 155/248 reads (63%) | catalogued as rs765683386; called by muse, mutect2, varscan2
- VAV3 | c.255G>A p.T85= | Silent (SNP) | VAF 65/307 reads (21%) | catalogued as rs563011711; called by muse, mutect2, varscan2
- ZFC3H1 | c.5697T>C p.Y1899= | Silent (SNP) | VAF 74/239 reads (31%) | catalogued as rs1377796832; called by muse, mutect2, varscan2
- AC092073.1 | c.193+3955A>G | Intron (SNP) | VAF 96/332 reads (29%) | called by muse, mutect2, varscan2
- ATXN8OS | n.252G>A | RNA (SNP) | VAF 61/233 reads (26%) | called by muse, mutect2, varscan2
- C6orf223 | n.624G>A | RNA (SNP) | VAF 166/555 reads (30%) | catalogued as rs1332474384; called by muse, mutect2, varscan2
- CACNB2 | c.214-854G>T | Intron (SNP) | VAF 98/369 reads (27%) | catalogued as COSV56626131; called by muse, mutect2, varscan2
- IL4I1 | chr19:49901715 C>A | 5'Flank (SNP) | VAF 83/288 reads (29%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+586A>G | Intron (SNP) | VAF 96/301 reads (32%) | catalogued as COSV56807911; called by muse, mutect2, varscan2
- SPATA32 | c.*1C>T | 3'UTR (SNP) | VAF 80/347 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.10303+2475C>T | Intron (SNP) | VAF 82/326 reads (25%) | catalogued as rs373473272; called by mutect2, varscan2
- Z99774.2 | chr22:26675151 C>T | 3'Flank (SNP) | VAF 86/369 reads (23%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-862G>T | Intron (SNP) | VAF 42/480 reads (9%) | called by muse, mutect2
